Somatic mutation profile of tumor specimen TARGET-20-PANCSC-09A (aliquot TARGET-20-PANCSC-09A-03D) from TARGET case TARGET-20-PANCSC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.7 years (3,890 days).
Specimen TARGET-20-PANCSC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b8c0e3e-126a-4eef-8557-724af1edd365.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANCSC-14A (Bone Marrow Normal), aliquot TARGET-20-PANCSC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/852c58ed-d09d-47c5-8a17-020ad028364d

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF3R | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796065343, COSV58963463; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WT1 | c.1264_1265insTG p.R422Lfs*16 | Frame Shift Ins (INS) | VAF 99/212 reads (47%) | catalogued as COSV60070980, COSV60080799, COSV60083260; called by mutect2, pindel, varscan2
